Somatic mutation profile of tumor specimen MBCProject_0734_T1B_WES (aliquot MBCProject_0734_T1B_WES_1) from CMI case MBCProject_0734, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.1 years (20,505 days).
Specimen MBCProject_0734_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eb601b9-1f05-4665-85fa-d89f5ca53ca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0734_SALIVA (Saliva), aliquot MBCProject_0734_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1aa698b-324c-4a2f-bdc3-5bd4597ae778

The open-access MAF lists 71 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Intron 6, Nonsense Mutation 5, Frame Shift Del 4, RNA 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 89/266 reads (33%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3130A>T p.N1044Y | Missense Mutation (SNP) | VAF 14/107 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.5); PolyPhen possibly damaging (0.511); catalogued as COSV55879195, COSV55892181, COSV99029255; called by muse, mutect2, varscan2
- AGPAT1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61247913; called by muse, mutect2, varscan2
- CDC42BPG | c.4544G>A p.S1515N | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs1358411013; called by muse, varscan2
- CLCN4 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760806121; called by muse, mutect2, varscan2
- DENND2B | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs1429724223; called by muse, varscan2
- DNAH7 | c.6554G>T p.R2185L | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56763812; called by muse, mutect2, varscan2
- FOCAD | c.4604G>T p.G1535V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as COSV100620441; called by muse, mutect2, varscan2
- FZD10 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1421592086; called by muse, mutect2, varscan2
- POLG | c.3211C>T p.R1071C | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs762593265, COSV51524432; ClinVar: uncertain significance; called by muse, mutect2
- PRAMEF4 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 237/643 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775644555, COSV52439564; called by muse, mutect2, varscan2
- PRICKLE2 | c.1781A>G p.Q594R (on ENST00000295902; = p.Q538R on NM_198859.4) | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs760909510; called by muse, mutect2, varscan2
- PRSS53 | c.849G>C p.E283D | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54923717; called by muse, mutect2, varscan2
- RANBP2 | c.9446A>T p.D3149V | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1558944272, COSV51698380; called by muse, mutect2, varscan2
- SCN4A | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772704244, COSV71126642, COSV71127867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELE | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 37/182 reads (20%) | catalogued as COSV100324796; called by muse, mutect2, varscan2
- SLITRK2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100157387; called by muse, mutect2
- SPATA31D1 | c.3027C>A p.D1009E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.172); catalogued as rs1199698893; called by muse, mutect2, varscan2
- SRC | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs142822674; called by muse, mutect2, varscan2
- TMED4 | c.251C>G p.P84R | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99215635; called by muse, mutect2, varscan2
- TTN | c.37975G>C p.V12659L (on ENST00000591111; = p.V5235L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | PolyPhen benign (0.011); catalogued as rs757079194, COSV100590544; called by muse, mutect2, varscan2
- AFF2 | c.3206T>A p.V1069D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ANK1 | c.4183G>C p.G1395R | Missense Mutation (SNP) | VAF 136/693 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKZF1 | c.2138del p.C713Sfs*36 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- ARID1A | c.4012dup p.S1338Ffs*107 | Frame Shift Ins (INS) | VAF 28/125 reads (22%) | called by pindel, varscan2
- DBH | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DISP3 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.9067C>T p.Q3023* | Nonsense Mutation (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- EPS8L1 | c.1664del p.P555Lfs*105 (on ENST00000201647 / NM_133180.3; = p.P428Lfs*105 on NM_017729.3) | Frame Shift Del (DEL) | VAF 91/548 reads (17%) | called by mutect2, pindel, varscan2
- HMMR | c.1808A>G p.E603G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HNRNPUL1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KCNH7 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRC2 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- NOS1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN3 | c.2075del p.N692Mfs*10 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- RECQL5 | c.2683T>A p.L895M | Missense Mutation (SNP) | VAF 193/761 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHOBTB2 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF114 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCML2 | c.1413G>T p.R471S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by mutect2, varscan2
- SELENOI | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SFRP1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 98/535 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SNX27 | c.612C>G p.H204Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SYBU | c.1688A>C p.N563T (on ENST00000276646 / NM_001099754.2; = p.N562T on NM_017786.6) | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRPM1 | c.3107A>G p.D1036G | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2
- TSHR | c.1169_1176del p.C390* | Frame Shift Del (DEL) | VAF 62/327 reads (19%) | called by mutect2, pindel, varscan2
- USP12 | c.983G>A p.W328* | Nonsense Mutation (SNP) | VAF 33/227 reads (15%) | called by muse, mutect2, varscan2
- ZNF536 | c.1243A>T p.M415L | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST2 | c.555C>T p.C185= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs778305142; called by muse, mutect2, varscan2
- EXOSC9 | c.339G>A p.S113= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs368408281; called by muse, mutect2, varscan2
- FAT3 | c.10803C>T p.H3601= | Silent (SNP) | VAF 47/232 reads (20%) | catalogued as rs571074322, COSV53164930, COSV99972442; called by muse, mutect2, varscan2
- LRRC59 | c.660A>G p.E220= | Silent (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2
- MATR3 | c.2115T>C p.S705= | Silent (SNP) | VAF 29/183 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.669C>T p.S223= | Silent (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- PLXNB3 | c.2682G>A p.V894= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- SASH3 | c.627T>A p.P209= | Silent (SNP) | VAF 42/346 reads (12%) | called by muse, mutect2, varscan2
- SLITRK2 | c.399G>T p.L133= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- SPAG4 | c.657C>G p.L219= | Silent (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- SPSB4 | c.135G>A p.A45= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs773533519; called by muse, mutect2, varscan2
- TCP11X2 | c.726C>T p.T242= | Silent (SNP) | VAF 36/336 reads (11%) | called by mutect2, varscan2
- UGT2B28 | c.852T>C p.P284= | Silent (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- ZNF98 | c.1107G>A p.K369= | Silent (SNP) | VAF 46/297 reads (15%) | called by muse, varscan2
- ARMCX4 | c.1039-4050G>C | Intron (SNP) | VAF 12/84 reads (14%) | catalogued as rs781960872, COSV61448686; called by muse, varscan2
- ARMCX4 | c.1039-4043G>A | Intron (SNP) | VAF 11/65 reads (17%) | catalogued as rs782152145, COSV61449103; called by muse, varscan2
- BCL11B | c.*1del | 3'UTR (DEL) | VAF 52/205 reads (25%) | called by mutect2, pindel, varscan2
- COX6A1P2 | n.75G>A | RNA (SNP) | VAF 91/411 reads (22%) | catalogued as rs778583585; called by muse, mutect2, varscan2
- DLGAP4 | c.1648+15550C>T | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs1488835131; called by muse, mutect2, varscan2
- HLA-L | n.550C>T | RNA (SNP) | VAF 57/315 reads (18%) | called by muse, mutect2, varscan2
- MASP2 | c.544+87G>A | Intron (SNP) | VAF 96/380 reads (25%) | catalogued as rs565301468, COSV101280239; called by muse, mutect2, varscan2
- MDFIC | c.-107-29_-107-24del | Intron (DEL) | VAF 42/120 reads (35%) | called by mutect2, pindel
- SMARCA4 | c.3168+15G>A | Intron (SNP) | VAF 116/350 reads (33%) | called by muse, mutect2, varscan2
